Surgical pathology report (de-identified scan), TCGA case TCGA-86-8055, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8055-01A (Primary Tumor).

[page 1 of 2]
		Gross Description	Microscopic Description	Diagnosis Details	Comments
ID	OpenClinica ID				

[page 2 of 2]
Formatted Path Report	Laterality/location		Date of excision
LUNG TISSUE CHECKLIST Specimen type: Pulmonectomy Tumor site: Lung Tumor size: 3.5 x 3.3 x 3.3 cm Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Visceral pleura Other tumor nodules: Not specified Lymph nodes: 5/5 positive for metastasis (Intrathoracical 5/5) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	Left- upper		

Source: NCI Genomic Data Commons file b6753833-dbb8-40a8-9636-4d67d85cae19 (TCGA-86-8055.B0F478A2-7696-4FC2-BDC9-839142556B6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).